Somatic mutation profile of tumor specimen MP2PRT-PARRAW-TBP1-A (aliquot MP2PRT-PARRAW-TBP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARRAW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,079 days).
Specimen MP2PRT-PARRAW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b8d7d7e-65d8-4816-a246-5cd972fd7e22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRAW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRAW-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da6b2fc4-b3f1-468d-a47f-75e1a4e393e3

The open-access MAF lists 67 somatic variants for this specimen: 44 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 39, Silent 23, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/626 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 115/805 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4676C>T p.S1559F | Missense Mutation (SNP) | VAF 117/783 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs768264506, COSV61259879, COSV61283179; called by muse, mutect2, varscan2
- ADGRD2 | c.177del p.G60Afs*66 | Frame Shift Del (DEL) | VAF 170/870 reads (20%) | catalogued as COSV99080218; called by mutect2, pindel, varscan2
- ADH6 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372810923; called by muse, mutect2, varscan2
- AL645922.1 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 149/985 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.11); catalogued as rs1395795972, COSV100191092; called by muse, mutect2, varscan2
- ANKRD30A | c.3565G>A p.E1189K (on ENST00000611781; = p.E1133K on NM_052997.2) | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100654309; called by muse, mutect2, varscan2
- BANP | c.761C>T p.T254M (on ENST00000286122; = p.T223M on NM_017869.4) | Missense Mutation (SNP) | VAF 152/892 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321416610; called by muse, mutect2
- C2CD4B | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 60/528 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1381338188; called by muse, mutect2
- CACNA1D | c.6331G>A p.V2111M (on ENST00000350061 / NM_001128840.3; = p.V2131M on NM_000720.4) | Missense Mutation (SNP) | VAF 143/882 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs371604022; called by muse, mutect2, varscan2
- COL6A1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 84/756 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs181256566, COSV62611743; called by muse, mutect2, varscan2
- EGFLAM | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 126/784 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59313148, COSV59319575; called by muse, mutect2, varscan2
- ERLEC1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 144/614 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.069); catalogued as COSV51753725; called by muse, varscan2
- GPBP1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 61/597 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.244); catalogued as rs779364379; called by muse, mutect2
- IFT74 | c.1700G>T p.S567I | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1482975341; called by mutect2, varscan2
- KCNB2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 158/829 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73051722; called by muse, mutect2, varscan2
- LMO3 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 60/445 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763918054; called by muse, mutect2, varscan2
- MIA2 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 62/420 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774797085, COSV54482575; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2288C>A p.S763* | Nonsense Mutation (SNP) | VAF 91/452 reads (20%) | catalogued as COSV64058446; called by muse, mutect2, varscan2
- MYO15A | c.6436C>T p.R2146W | Missense Mutation (SNP) | VAF 133/834 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375805896; called by muse, mutect2, varscan2
- NPHS1 | c.3367C>T p.R1123W | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs373931233, COSV62289195; called by muse, varscan2
- PATJ | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 100/616 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs554320651, COSV57164204; called by muse, mutect2, varscan2
- RYR3 | c.9757G>A p.E3253K (on ENST00000389232; = p.E3254K on NM_001036.6) | Missense Mutation (SNP) | VAF 99/636 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as rs774163504, COSV66791228; called by muse, mutect2, varscan2
- SYNE1 | c.23176G>A p.D7726N (on ENST00000367255 / NM_182961.4; = p.D7655N on NM_033071.3) | Missense Mutation (SNP) | VAF 68/532 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV55112720; called by muse, mutect2, varscan2
- TOPAZ1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV104399944, COSV59064250; called by muse, mutect2, varscan2
- ADCK1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 108/904 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ARHGEF38 | c.2083G>A p.G695S | Missense Mutation (SNP) | VAF 108/701 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- COL6A1 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 166/1188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMGDH | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 73/463 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- EIF1AY | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ENPP2 | c.1969G>A p.V657I (on ENST00000075322 / NM_001040092.3; = p.V709I on NM_006209.5) | Missense Mutation (SNP) | VAF 174/529 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ETV6 | c.460dup p.E154Gfs*3 | Frame Shift Ins (INS) | VAF 70/522 reads (13%) | called by mutect2, pindel, varscan2
- FAM111B | c.144_147del p.R48Sfs*26 | Frame Shift Del (DEL) | VAF 65/416 reads (16%) | called by mutect2, pindel, varscan2
- FBXW12 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- IDH2 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 123/937 reads (13%) | called by muse, mutect2, varscan2
- KCNA6 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 175/992 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by muse, varscan2
- OR2F1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 93/574 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCL1 | c.1728G>T p.Q576H | Missense Mutation (SNP) | VAF 80/550 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMXL3 | c.674C>A p.A225D | Missense Mutation (SNP) | VAF 259/889 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- RIPOR1 | c.229C>T p.R77W (on ENST00000379312 / NM_001193522.2; = p.R73W on NM_024519.4) | Missense Mutation (SNP) | VAF 187/1013 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBKBP1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 206/1131 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TRDD3 | chr14:22449106 CACTGTGA>GTG | Missense Mutation (DEL) | VAF 43/181 reads (24%) | called by pindel, varscan2*
- WDR44 | c.2139T>G p.D713E | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPC | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 140/864 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ADRA2A | c.204C>A p.L68= | Silent (SNP) | VAF 250/1481 reads (17%) | catalogued as rs368175821; called by muse, mutect2, varscan2
- CFAP46 | c.1452C>T p.R484= | Silent (SNP) | VAF 156/771 reads (20%) | catalogued as rs936095223; called by muse, mutect2, varscan2
- CRYBG3 | c.7902G>A p.G2634= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as rs1247258872; called by muse, mutect2, varscan2
- DNAH2 | c.6126C>A p.G2042= | Silent (SNP) | VAF 75/450 reads (17%) | called by muse, mutect2, varscan2
- DNAH5 | c.12006C>T p.S4002= | Silent (SNP) | VAF 40/380 reads (11%) | catalogued as rs867648164; called by muse, mutect2, varscan2
- EVC2 | c.2523C>T p.F841= | Silent (SNP) | VAF 104/576 reads (18%) | called by muse, mutect2, varscan2
- FAM184A | c.39C>T p.Y13= | Silent (SNP) | VAF 160/1028 reads (16%) | called by muse, mutect2, varscan2
- FHOD3 | c.1941C>T p.S647= (on ENST00000359247 / NM_001281739.3; = p.S664= on NM_025135.5) | Silent (SNP) | VAF 99/514 reads (19%) | called by muse, mutect2, varscan2
- FURIN | c.1710C>T p.L570= | Silent (SNP) | VAF 116/625 reads (19%) | called by muse, mutect2, varscan2
- GOLGA6L10 | c.222C>T p.Y74= | Silent (SNP) | VAF 44/782 reads (6%) | catalogued as rs1369689431; called by muse, mutect2
- GPBP1 | c.39C>T p.F13= | Silent (SNP) | VAF 61/599 reads (10%) | called by muse, mutect2
- GRM5 | c.2196C>T p.I732= | Silent (SNP) | VAF 129/629 reads (21%) | catalogued as rs1173018044; called by muse, mutect2, varscan2
- HCFC1 | c.3075C>T p.T1025= | Silent (SNP) | VAF 221/829 reads (27%) | called by muse, mutect2, varscan2
- IL23R | c.1545C>T p.S515= | Silent (SNP) | VAF 31/206 reads (15%) | catalogued as COSV61373794; called by muse, mutect2, varscan2
- KRTAP10-3 | c.228G>A p.T76= | Silent (SNP) | VAF 125/1213 reads (10%) | catalogued as rs781984633; called by muse, mutect2, varscan2
- NME9 | c.720C>T p.D240= (on ENST00000333911 / NM_001349024.2; = p.D179= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 150/837 reads (18%) | catalogued as rs377196410; called by muse, mutect2, varscan2
- OBSCN | c.23196C>T p.H7732= | Silent (SNP) | VAF 208/902 reads (23%) | catalogued as rs571437600; called by muse, mutect2, varscan2
- SCNN1G | c.1869G>A p.P623= | Silent (SNP) | VAF 152/925 reads (16%) | catalogued as rs781731308; called by muse, mutect2, varscan2
- SLC1A1 | c.1353C>T p.N451= | Silent (SNP) | VAF 164/450 reads (36%) | catalogued as rs1415538318, COSV52053939; called by muse, mutect2, varscan2
- TACC2 | c.6048G>A p.P2016= (on ENST00000334433; = p.P94= on NM_006997.4) | Silent (SNP) | VAF 86/650 reads (13%) | catalogued as rs143883746; called by muse, mutect2, varscan2
- TAS2R1 | c.192C>T p.Y64= | Silent (SNP) | VAF 98/539 reads (18%) | catalogued as rs139834398, COSV101225837; called by muse, mutect2, varscan2
- TEX11 | c.1383G>A p.R461= (on ENST00000344304; = p.R446= on NM_031276.3) | Silent (SNP) | VAF 94/312 reads (30%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8028G>A p.R2676= | Silent (SNP) | VAF 153/883 reads (17%) | catalogued as rs765387491, COSV51498267; called by muse, mutect2, varscan2
